Gene-level copy-number profile of tumor specimen TCGA-24-1474-01A from TCGA case TCGA-24-1474, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.2 years (20,902 days).
Specimen TCGA-24-1474-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.17d5600b-8927-444b-96b2-82a3c8a81001.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1474-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e0aa25e2-f3f3-4aa6-9e5a-c32dbf04b634

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,635; copy number 2: 8,782; copy number 3: 23,243; copy number 4: 11,535; copy number 5: 7,056; copy number 6: 6,124; copy number 7: 291; copy number 8: 237; copy number 9: 21; copy number 10: 253; copy number 11: 79; copy number 12: 70; copy number 13: 131; copy number 14: 70; copy number 15: 51; copy number 16: 28; copy number 17: 20; copy number 18: 108; copy number 20: 26; copy number 21: 38; copy number 25: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1474-01A-01D-0497-01): tumor purity 0.79, ploidy 3.77, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,438 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:19,312,326–20,354,894, 27 genes, copy number 16 (within-gene range 4–16): SLC66A1, CAPZB, RN7SL277P, MICOS10, RNU4-28P, AL031727.2, NBL1, MICOS10-NBL1, AL031727.1, HTR6, TMCO4, RNF186, AL391883.1, OTUD3, PLA2G2E, RN7SL304P, PLA2G2A, PLA2G5, PLA2G2D, PLA2G2F, Z98257.1, PLA2G2C, UBXN10, LINC01757, Z98257.2, VWA5B1, AL020998.1.
- chr1:22,428,838–24,364,482, 63 genes, copy number 12–17 (within-gene range 4–17) (broad region; genes not listed).
- chr1:40,691,648–41,484,683, 23 genes, copy number 7 (within-gene range 4–7): NFYC, MIR30E, MIR30C1, KCNQ4, RN7SL326P, CITED4, AC119677.1, AL391730.1, AL391730.2, UBE2V1P8, CTPS1, SLFNL1-AS1, SLFNL1, SCMH1, RPL23AP17, AC093151.7, AC093151.2, AC093151.1, AC093151.5, FOXO6, FOXO6-AS1, RNA5SP45, EDN2.
- chr1:41,535,443–41,544,310, 2 genes, copy number 7 (within-gene range 5–7): AL445933.2, AL445933.1.
- chr1:111,739,579–111,747,798, 1 gene, copy number 12 (within-gene range 4–12): INKA2-AS1.
- chr1:117,367,449–117,528,872, 2 genes, copy number 8 (within-gene range 4–8): MAN1A2, AL157902.2.
- chr1:158,878,746–158,883,500, 1 gene, copy number 16: PYHIN5P.
- chr1:176,367,699–186,522,304, 192 genes, copy number 9–25 (broad region; genes not listed).
- chr1:203,026,498–204,558,120, 52 genes, copy number 7 (within-gene range 5–7): PPFIA4, MYOG, ADORA1, AC105940.2, AC105940.1, MYBPH, CHI3L1, CHIT1, NPM1P40, LINC01353, LINC01136, BTG2, RNU6-487P, FMOD, AL359837.1, LARP7P1, PRELP, OPTC, ATP2B4, NSA2P1, SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1.
- chr2:106,697,331–108,265,351, 25 genes, copy number 9–12 (within-gene range 3–12): EEF1A1P12, ST6GAL2, ST6GAL2-IT1, AC016994.1, AC005040.2, PPP1R2P5, AC005040.1, LINC01789, AC096669.1, LINC01885, LINC01886, AC064869.1, GACAT1, RGPD4-AS1, RGPD4, AC009963.2, AC009963.1, RPL22P8, SRSF3P5, SLC5A7, LINC01593, ACTP1, LINC01594, SETD6P1, SULT1C3.
- chr2:142,131,178–142,137,830, 1 gene, copy number 12: AC078882.1.
- chr2:162,371,407–163,289,096, 5 genes, copy number 12 (within-gene range 3–12): KCNH7, RNA5SP109, KCNH7-AS1, RPL7P61, RNU6-627P.
- chr2:176,121,611–176,137,098, 1 gene, copy number 13 (within-gene range 3–13): HOXD-AS2.
- chr2:176,136,612–179,861,612, 85 genes, copy number 7–13 (within-gene range 6–13) (broad region; genes not listed).
- chr2:182,140,036–182,523,192, 3 genes, copy number 12 (within-gene range 3–12): PDE1A, AC012500.1, RN7SL267P.
- chr3:1,595,777–1,987,470, 4 genes, copy number 7: RPL23AP38, RPL23AP39, RPL21P17, AC018814.1.
- chr3:96,244,732–96,567,103, 4 genes, copy number 8: AC107304.1, HNRNPKP4, MIR8060, AC107015.1.
- chr4:705,748–2,418,651, 57 genes, copy number 8–21 (within-gene range 3–21): PCGF3, AC107464.1, AC139887.4, AC139887.2, AC139887.1, CPLX1, AC139887.3, AC139887.5, GAK, TMEM175, DGKQ, SLC26A1, IDUA, FGFRL1, AC019103.1, RNF212, AC092535.3, AC092535.4, TMED11P, AC092535.1, AC092535.2, SPON2, AC092535.5, CTBP1-AS, CTBP1, CTBP1-DT, MAEA, UVSSA, AC078852.2, AC078852.1, NKX1-1, AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2, SCARNA22, NELFA, MIR943, C4orf48, NAT8L, POLN, HAUS3, AL136360.1, COX6B1P5, MXD4, MIR4800, ZFYVE28, AL158068.2, RN7SL589P, AL158068.1.
- chr4:41,220,074–43,234,956, 33 genes, copy number 8: UCHL1-AS1, UCHL1, Y_RNA, LIMCH1, RPL12P20, AC108050.1, AC105389.2, OR5M14P, PHOX2B, PHOX2B-AS1, AC105389.1, RNU1-49P, HMGB1P28, LINC00682, AC108210.1, AC108210.2, TMEM33, DCAF4L1, AC106052.1, SLC30A9, ATP1B1P1, BEND4, AC111006.1, AC024022.1, SHISA3, ATP8A1, RPS7P7, CCNL2P1, AC096734.2, AC096734.1, RN7SKP82, GRXCR1, AC111198.1.
- chr5:17,601,882–22,853,344, 50 genes, copy number 7 (within-gene range 4–7): AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20, H3P21, TAF11L13, TAF11L14, AC233724.4, AC233724.1, AC233724.5, AC233724.2, H3Y1, AC233724.8, H3P22, LINC02223, RPL36AP21, SNORD81, RN7SL58P, LINC02100, UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15, CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1.
- chr8:50,762,460–54,871,720, 59 genes, copy number 7 (within-gene range 4–7): CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1, NPBWR1, AC009800.1, AC009646.1, AC009646.2, OPRK1, AC131902.1, AC022034.3, AC131902.2, AC022034.1, AC022034.4, AC022034.2, MAPK6P1, AC103778.1, ATP6V1H, RGS20, AC113194.1, RPS27AP13, RNU6-1331P, TCEA1, AC100821.1, AC100821.2, LYPLA1, TDGF1P5, Metazoa_SRP, MRPL15, RNU6ATAC32P, AC060764.1, AC044836.1, RNU105C, AC027250.1, AC027250.2, RN7SL250P, SOX17, AC091076.1, TRMT112P7, RP1, SEC11B.
- chr8:126,474,189–128,220,803, 33 genes, copy number 17–20: AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226.
- chr8:129,728,744–133,963,259, 61 genes, copy number 13–15 (broad region; genes not listed).
- chr10:4,415,305–8,973,468, 101 genes, copy number 8–13 (broad region; genes not listed).
- chr10:30,403,197–33,082,102, 50 genes, copy number 10–15 (within-gene range 3–15): CCND3P1, MAP3K8, HNRNPA1P32, AL590068.4, AL590068.1, RN7SL63P, AL590068.2, AL590068.3, LYZL2, SVIL2P, LINC02644, ZNF438, AL359532.1, DDX10P1, AL359546.1, LINC02664, ZEB1-AS1, RNA5SP309, ZEB1, SPTLC1P1, AL117340.1, AL161935.1, AL161935.3, AL161935.2, MACORIS, Y_RNA, ARHGAP12, HMGB1P7, RPL34P19, RN7SL825P, KIF5B, Y_RNA, RPS4XP11, AL161932.2, AL161932.1, RNU7-22P, PPIAP31, RPS24P13, AL158834.2, EPC1, AL158834.1, AL391839.2, AL391839.1, RNU6-1244P, AL391839.3, CCDC7, C1DP1, ITGB1, AK3P5, ITGB1-DT.
- chr12:22,008,348–22,437,041, 7 genes, copy number 7: AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1.
- chr12:22,460,519–22,463,914, 1 gene, copy number 7: AC053513.2.
- chr14:29,952,397–30,895,065, 15 genes, copy number 14 (within-gene range 6–14): AL133372.2, AL133372.1, AL079305.1, G2E3-AS1, AL117355.1, SYF2P1, G2E3, SCFD1, UBE2CP1, AL121852.1, RPL12P5, AL049830.2, AL049830.1, COCH, AL049830.3.
- chr17:33,013,087–34,174,964, 1 gene, copy number 8 (within-gene range 6–11): ASIC2.
- chr17:33,529,787–34,639,318, 31 genes, copy number 8–11: AA06, AC011824.3, AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3, AC024614.4, AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102, TMEM132E, AC005691.1.
- chr19:9,261,015–16,892,606, 446 genes, copy number 7–10 (broad region; genes not listed).
- chr19:16,907,462–16,910,784, 2 genes, copy number 7: RN7SL835P, RN7SL823P.

Autosomal genes at a single copy (total copy number 1): 919. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
